Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HM, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HM-01A (Primary Tumor).

Synoptic translated report

TCR-0-3

Carcinoma, Squamous cell NOS
807013
Site: R Lung, upper lobe
(B4.1)
W 2/1/13

Site :

1. Right lung inferior lobe
2. Right lung superior lobe

☐ Central
☒ Peripheral
☐ NA

Number of lesion :

1. Lung squamous cell carcinoma
2. Lung adenocarcinoma

Tumor size:

1. 5.5 x 5.0 x 3.5 cm
2. 3.0 x 2.7 x 2.0 cm

Visceral pleural invasion:

☐ Yes
☒ No
☐ NA

Chest wall invasion :

☐ Yes
☒ No
☐ NA

Histological diagnosis :

1. Moderately to poorly differentiated squamous cell carcinoma (submitted frozen specimen)
2. Bronchioloalveolar adenocarcinoma

Node status : NO (0/52)

TNM : pT2a pN0 (0/52) R0 (squamous cell carcinoma)

Pathologist signature:

Date:

Source: NCI Genomic Data Commons file efaa58e0-3a4d-4ccc-994f-12617d5ee4fa (TCGA-NC-A5HM.116B2CC4-B716-4CB4-852C-5EF15ED95FBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).